Gene-level copy-number profile of tumor specimen HTMCP-03-06-02238-01A from CGCI case HTMCP-03-06-02238, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 40.9 years (14,943 days).
Specimen HTMCP-03-06-02238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 72480414-c6f8-4f08-90cb-f219bd790f08.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02238-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/f41e7757-7488-481a-9836-998b6fab0ebf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 26; copy number 2: 11,726; copy number 3: 30,824; copy number 4: 12,592; copy number 5: 2,569; copy number 6: 39; copy number 8: 612; copy number 9: 7.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 619 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 9: CFHR3.
- chr13:55,535,697–114,337,626, 618 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
